Surgical pathology report (de-identified scan), TCGA case TCGA-HE-A5NK, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HE-A5NK-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	renal cell carcinoma, papillary type
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	renal and ureter - kidney
Tumour Size (cm)	6
Histology	renal cell carcinoma, papillary type
Grade/Differentiation	IV
Pathological T	T1b
Pathological N	NX
Clinical M	M0
Histology Comments	

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD0-3
Carcinoma, papillary renal cell 8260/3
Site: Kidney NOS C64.9
NO 2/11/13

Criteria	lw 2/7/13	Yes	No

Source: NCI Genomic Data Commons file 1f289103-b571-4630-a8c0-a98c16eccf36 (TCGA-HE-A5NK.3198202A-AFF1-4ABD-B0AD-B568341A1E9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).